Gene-level copy-number profile of specimen HCM-BROD-0335-C43-85M from HCMI case HCM-BROD-0335-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 61.7 years (22,537 days).
Specimen HCM-BROD-0335-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 14.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a7524940-fffd-42bb-830d-d4bbd040cc11.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0335-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/7876d6c5-ea83-4c72-b70e-ddacb74dea76

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,520; copy number 2: 27,076; copy number 3: 18,571; copy number 4: 7,761; copy number 5: 581; copy number 6: 2; copy number 7: 1,899; copy number 8: 1,494.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,976 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:58,427,799–59,063,766, 2 genes, copy number 5 (within-gene range 5–6): LINC01122, AC007238.1.
- chr2:203,867,771–203,873,965, 1 gene, copy number 5: CTLA4.
- chr2:221,162,771–221,163,053, 1 gene, copy number 5: AC011233.1.
- chr2:222,404,985–222,709,930, 9 genes, copy number 5: Y_RNA, SGPP2, NANOGP2, RNU6-619P, GAPDHP49, FARSB, MOGAT1, RRAS2P2, AC104772.1.
- chr2:223,248,498–227,164,453, 33 genes, copy number 5 (within-gene range 5–6): RN7SL807P, HIGD1AP4, AC013448.1, AC013448.2, SCG2, MLXP1, AP1S3, AC093884.1, WDFY1, MRPL44, AC073641.1, SERPINE2, USP21P1, AC008072.1, FAM124B, AC073052.1, CUL3, ANKRD49P1, DOCK10, MIR4439, NYAP2, AC016717.1, AC016717.2, AC016717.3, AC068138.1, AC062015.1, MIR5702, IRS1, AC010735.2, AC010735.1, RHBDD1, AC073149.1, COL4A4.
- chr2:227,683,763–227,718,028, 1 gene, copy number 5: SLC19A3.
- chr2:228,475,224–228,841,689, 3 genes, copy number 5: LINC01807, AC012070.1, RPL7L1P10.
- chr6:485,154–796,781, 9 genes, copy number 5: EXOC2, AL031770.1, HUS1B, AL357054.1, AL357054.2, AL357054.4, AL357054.5, AL357054.3, AL392183.1.
- chr6:3,585,101–4,189,806, 24 genes, copy number 5: AL033523.1, AL033523.2, PXDC1, AL391422.4, AL391422.1, AL391422.3, AL391422.2, FAM50B, AL590004.3, AL590004.2, AL590004.1, TDGF1P4, GLRX3P2, AL138831.3, AL138831.2, AL138831.1, PRPF4B, FAM217A, C6orf201, ECI2, AL136309.3, ECI2-DT, AL136309.2, AL136309.1.
- chr6:18,522,735–18,674,001, 2 genes, copy number 5: MIR548A1HG, MIR548A1.
- chr6:20,401,879–20,500,276, 5 genes, copy number 5: E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA.
- chr6:21,664,185–22,654,455, 5 genes, copy number 5 (within-gene range 4–5): CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1.
- chr6:22,569,566–22,571,666, 1 gene, copy number 5: HDGFL1.
- chr6:22,744,395–23,031,780, 1 gene, copy number 5: AL035401.1.
- chr6:31,268,749–31,272,130, 1 gene, copy number 5: HLA-C.
- chr6:31,307,815–35,797,344, 273 genes, copy number 5 (broad region; genes not listed).
- chr6:35,943,516–37,819,218, 53 genes, copy number 5: SLC26A8, DPRXP2, MAPK14, Z95152.1, MAPK13, Z84485.1, BRPF3, PNPLA1, BNIP5, ETV7, ETV7-AS1, PXT1, KCTD20, RN7SL502P, STK38, RN7SL748P, SRSF3, MIR3925, RNU1-88P, Y_RNA, PANDAR, LAP3P2, CDKN1A, DINOL, RAB44, Z85996.1, CPNE5, Z85996.2, PPIL1, C6orf89, AL122034.1, PI16, MTCH1, FGD2, COX6A1P2, RPL12P2, PIM1, TMEM217, AL353579.1, TBC1D22B, AL096712.1, AL096712.2, RNF8, RN7SL273P, CMTR1, CCDC167, LINC02520, AL353597.2, AL353597.1, MIR4462, AL353597.3, MDGA1, AL121574.1.
- chr6:38,168,451–38,640,148, 1 gene, copy number 5 (within-gene range 4–5): BTBD9.
- chr6:38,481,692–42,722,597, 97 genes, copy number 5 (broad region; genes not listed).
- chr6:44,727,921–45,377,953, 2 genes, copy number 5 (within-gene range 4–5): AL133334.1, SUPT3H.
- chr6:45,097,496–45,197,770, 4 genes, copy number 5: AL138880.2, RBM22P4, AL138880.1, MIR586.
- chr6:52,739,590–52,909,698, 9 genes, copy number 5: GSTA7P, GSTA2, GSTA12P, GSTA1, GSTA6P, GSTA5, GSTA11P, GSTA10P, GSTA3.
- chr6:54,770,583–54,771,134, 1 gene, copy number 5: KRASP1.
- chr7:62,275,361–159,233,377, 1,899 genes, copy number 7 (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,494 genes, copy number 8 (broad region; genes not listed).
- chr17:81,387,415–81,390,319, 2 genes, copy number 5: AC110285.5, AC110285.2.
- chr17:82,314,868–82,363,775, 4 genes, copy number 5–6: CD7, SECTM1, TEX19, AC132938.4.
- chr21:7,744,962–9,059,060, 39 genes, copy number 5: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4.

Autosomal genes at a single copy (total copy number 1): 1,008. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
